Gene-level copy-number profile of tumor specimen MP2PRT-PAWRAM-TTM2-A from MP2PRT case MP2PRT-PAWRAM, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.1 years (1,130 days).
Specimen MP2PRT-PAWRAM-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f28abdcb-b592-445b-a37b-c480952a79dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAWRAM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/1b03be04-9481-4e43-a029-f9b0ca801f33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,973; copy number 2: 32,508; copy number 3: 19,747; copy number 4: 2,672; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:112,967–186,136, 5 genes (within-gene range 0–1): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,878,790–64,889,063, 2 genes, copy number 5: AC125634.1, RNU6-1293P.

Autosomal genes at a single copy (total copy number 1): 1,127. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
